Gene-level copy-number profile of tumor specimen TCGA-B5-A0JN-01A from TCGA case TCGA-B5-A0JN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-B5-A0JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.40e8e0af-0ac6-4b5a-8db8-e33d4d17430d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A0JN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7c3f8738-51f4-49b4-b953-f3b3d10808d1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 200; copy number 2: 16,189; copy number 3: 26,396; copy number 4: 10,985; copy number 5: 3,738; copy number 6: 601; copy number 7: 1,060; copy number 8: 386; copy number 9: 33; copy number 10: 63; copy number 11: 109; copy number 12: 12; copy number 15: 1; copy number 17: 15; copy number 20: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A0JN-01A-11D-A102-01): tumor purity 0.74, ploidy 3.23, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:39,016,047–40,144,504, 15 genes: RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,653 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:159,771,851–159,904,710, 1 gene, copy number 7 (within-gene range 4–7): LY75-CD302.
- chr2:159,803,355–159,904,756, 1 gene, copy number 7 (within-gene range 4–7): LY75.
- chr2:159,932,006–160,062,615, 1 gene, copy number 7 (within-gene range 4–7): PLA2R1.
- chr2:207,687,960–208,025,527, 7 genes, copy number 8 (within-gene range 4–8): Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1.
- chr2:217,799,588–218,254,356, 9 genes, copy number 7 (within-gene range 4–7): TNS1, MIR6809, TNS1-AS1, RUFY4, CXCR2P1, CXCR2, CXCR1, HMGB1P9, ARPC2.
- chr3:168,249,522–168,830,599, 1 gene, copy number 7 (within-gene range 5–7): EGFEM1P.
- chr3:168,475,198–169,038,416, 8 genes, copy number 7: RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr7:9,621,764–9,769,513, 1 gene, copy number 20 (within-gene range 3–38): AC060834.2.
- chr7:9,726,241–47,049,678, 635 genes, copy number 7–20 (within-gene range 5–20) (broad region; genes not listed).
- chr8:119,730,774–120,373,573, 10 genes, copy number 7 (within-gene range 5–7): TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:121,612,116–135,742,495, 221 genes, copy number 7–8 (broad region; genes not listed).
- chr8:135,977,329–136,295,232, 2 genes, copy number 7: AC103955.1, AC023781.1.
- chr11:62,049,863–62,556,235, 19 genes, copy number 7 (within-gene range 4–7): LINC02733, AP003733.2, AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2, AHNAK.
- chr12:68,841,288–69,422,995, 16 genes, copy number 8: AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45.
- chr13:105,459,055–105,702,689, 5 genes, copy number 8: DAOA-AS1, AL359751.2, AL359751.1, DAOA, AL359745.1.
- chr17:37,375,985–45,133,354, 441 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr18:22,088,060–38,688,033, 240 genes, copy number 7–15 (broad region; genes not listed).
- chr19:8,848,844–9,519,341, 32 genes, copy number 7: MUC16, BOLA3P2, OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266, AC011451.4, ZNF560, AC008567.2, AC008567.3, AC008567.1.
- chr20:51,831,797–51,905,030, 3 genes, copy number 8: LINC01429, RNU6-347P, RNU7-6P.

Autosomal genes at a single copy (total copy number 1): 194. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
